TARGET case TARGET-40-NAAEDD — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/99c1f02d-1c90-52a8-9ba3-719373f63eeb

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 13 years; Vital status: Dead; Days to death: 378 days (1.0 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.4; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 13.7 years (5,015 days); Year of diagnosis: 2006; Metastasis at diagnosis: No Metastasis; Days to last follow up: 378 days (1.0 years).
   Pathology details: Necrosis percent: 10.
   Treatment given: Protocol identifier: OSTEO 2006.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Methotrexate.

Follow-up (3 entries)
- Days to follow up: 154 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 154 days.
- Days to follow up: 167 days; Days to first event: 167 days; First event: Progression.
- Days to follow up: 378 days (1.0 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2007.

Biospecimens (2 samples)
- Sample TARGET-40-NAAEDD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAEDD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDD-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 95
- % Non Tumor Nuclei: Top from Biopsy: 5
- % Cellular Tumor: Top from Biopsy: 85
- % Normal: Top from Biopsy: 10
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 2
- % Tumor Nuclei: Bottom from Biopsy: 90
- % Non Tumor Nuclei: Bottom from Biopsy: 10
- % Cellular Tumor: Bottom from Biopsy: 78
- % Normal: Bottom from Biopsy: 2
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 20
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDD-06A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 95
- % Non Tumor Nuclei: Top from Biopsy: 5
- % Cellular Tumor: Top from Biopsy: 85
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 0
- % Tumor Nuclei: Bottom from Biopsy: 95
- % Non Tumor Nuclei: Bottom from Biopsy: 5
- % Cellular Tumor: Bottom from Biopsy: 50
- % Normal: Bottom from Biopsy: 0
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 50
- PASS/FAIL: fail - 32% NC

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDD-08A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: no
- % Tumor Nuclei: Top from Biopsy: 0
- % Non Tumor Nuclei: Top from Biopsy: 100
- % Cellular Tumor: Top from Biopsy: 0
- % Normal: Top from Biopsy: 100
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 0
- % Tumor Nuclei: Bottom from Biopsy: 0
- % Non Tumor Nuclei: Bottom from Biopsy: 100
- % Cellular Tumor: Bottom from Biopsy: 0
- % Normal: Bottom from Biopsy: 100
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 0
- PASS/FAIL: fail

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 378
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Pelvis
- Specific tumor site: Ilium
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Site of initial relapse: Lung
- Time to first relapse in days: 154
- Time to first enrollment on relapse protocol in days: 224
- Time to first SMN in days: 0
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Relapse Type: Systemic, Locally recurrent
- Therapy: CIS+DOX+MTX
